Somatic mutation profile of tumor specimen TCGA-BR-6705-01A (aliquot TCGA-BR-6705-01A-12D-1882-08) from TCGA case TCGA-BR-6705, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Body of stomach; AJCC pathologic stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 68.6 years (25,073 days).
Specimen TCGA-BR-6705-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d4081362-cacd-4369-bd95-24433b7263b4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BR-6705-10A (Blood Derived Normal), aliquot TCGA-BR-6705-10A-01D-1882-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dbca08e4-dc18-45d5-ad44-15b4e611b5c7

The open-access MAF lists 85 somatic variants for this specimen: 62 protein-altering or splice-affecting, 20 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 58, Silent 20, Nonsense Mutation 3, Splice Site 1, Intron 1, RNA 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACSS1 | c.703G>A p.V235M | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV60225832; called by mutect2, varscan2
- ADCY8 | c.1719G>T p.R573S | Missense Mutation (SNP) | VAF 18/264 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as COSV53932579; called by muse, mutect2
- ADGRL3 | c.3698G>A p.R1233H (on ENST00000506720 / NM_001322402.2; = p.R1165H on NM_015236.6) | Missense Mutation (SNP) | VAF 7/83 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.828); catalogued as COSV72232234; called by muse, mutect2
- AKAP6 | c.6337T>G p.L2113V | Missense Mutation (SNP) | VAF 14/166 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV55221082, COSV99797570; called by muse, mutect2
- ALMS1 | c.8000G>A p.G2667D | Missense Mutation (SNP) | VAF 16/128 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0.109); catalogued as COSV52508609, COSV52522882; called by muse, mutect2, varscan2
- ANO4 | c.164C>T p.A55V (on ENST00000392977 / NM_001286615.2; = p.A20V on NM_178826.4) | Missense Mutation (SNP) | VAF 12/136 reads (9%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as rs1275759111, COSV54617434; called by muse, mutect2
- APOB | c.214A>C p.S72R | Missense Mutation (SNP) | VAF 22/175 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as COSV51957260; called by muse, mutect2, varscan2
- ATP13A5 | c.2933T>A p.F978Y | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.162); catalogued as COSV60876903; called by muse, mutect2, varscan2
- AXIN1 | c.1207C>T p.R403W | Missense Mutation (SNP) | VAF 5/62 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51988578; called by muse, mutect2
- B4GALNT2 | c.994C>T p.R332C | Missense Mutation (SNP) | VAF 21/242 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.511); catalogued as rs145043273; called by muse, mutect2
- CD1D | c.481T>G p.L161V | Missense Mutation (SNP) | VAF 54/324 reads (17%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs1173138241, COSV63808527, COSV63808964; called by muse, mutect2, varscan2
- CHD1L | c.1867G>T p.G623C | Missense Mutation (SNP) | VAF 10/268 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.944); catalogued as COSV100787310; called by muse, mutect2
- CLDN12 | c.692C>T p.S231F | Missense Mutation (SNP) | VAF 29/177 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55306187; called by muse, mutect2, varscan2
- CMYA5 | c.10150T>A p.F3384I | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.051); catalogued as COSV71410392; called by muse, mutect2, varscan2
- CNTNAP2 | c.1354G>A p.G452R | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.979); catalogued as rs1338220329, COSV62271316; called by muse, mutect2, varscan2
- DLG2 | c.159A>C p.Q53H (on ENST00000650630 / NM_001351274.2; = p.Q16H on NM_001142699.3) | Missense Mutation (SNP) | VAF 8/116 reads (7%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as COSV65883672; called by muse, mutect2
- DNAH11 | c.10286G>T p.R3429L | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs756115857, CM157451, COSV60966873, COSV60987236; called by muse, mutect2, varscan2
- EPB41 | c.2069A>T p.K690M (on ENST00000343067 / NM_001166005.2; = p.K448M on NM_004437.4) | Missense Mutation (SNP) | VAF 7/91 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV58050112, COSV58055522; called by muse, mutect2
- EPHB1 | c.2144A>T p.Q715L | Missense Mutation (SNP) | VAF 17/256 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV101212595, COSV67673862; called by muse, mutect2
- ETS2 | c.441T>A p.F147L | Missense Mutation (SNP) | VAF 32/260 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV62874817; called by muse, mutect2, varscan2
- FBXO28 | c.973C>T p.R325* | Nonsense Mutation (SNP) | VAF 8/185 reads (4%) | catalogued as COSV64800331; called by muse, mutect2
- FBXW4 | c.1672A>T p.N558Y | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.176); catalogued as COSV58710010; called by muse, mutect2, varscan2
- GAB4 | c.328T>G p.F110V | Missense Mutation (SNP) | VAF 37/359 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.424); catalogued as COSV68755448; called by muse, mutect2, varscan2
- GAPVD1 | c.1456A>C p.S486R | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV52928321; called by muse, mutect2, varscan2
- GFRAL | c.708C>G p.H236Q | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.084); catalogued as COSV61234566, COSV61236599; called by muse, mutect2
- GPD2 | c.881C>T p.T294M | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as rs769617848, COSV60097943; called by muse, mutect2, varscan2
- GRM8 | c.1862T>C p.L621P | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV58860130; called by muse, mutect2, varscan2
- GTF2IRD1 | c.2548C>T p.R850W (on ENST00000265755 / NM_016328.3; = p.R835W on NM_005685.4) | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs1554369353, COSV56092911; called by muse, mutect2, varscan2
- H2AC8 | c.31G>A p.A11T | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as rs761349300, COSV55128056, COSV55128074; called by muse, mutect2, varscan2
- HINFP | c.1168C>T p.R390W | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs867721201, COSV63432592; called by muse, mutect2, varscan2
- IGHMBP2 | c.167G>A p.R56H | Missense Mutation (SNP) | VAF 14/137 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as rs571887680, COSV54821303; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- IL17RE | c.1040A>G p.N347S | Missense Mutation (SNP) | VAF 10/224 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.432); catalogued as COSV55971372; called by muse, mutect2
- KLHL13 | c.1799G>A p.R600H | Missense Mutation (SNP) | VAF 18/193 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); catalogued as rs927520673, COSV53254145; called by muse, mutect2
- KRAS | c.404G>C p.R135T | Missense Mutation (SNP) | VAF 24/484 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV55890841, COSV56142467; called by muse, mutect2
- LRIG1 | c.3259C>G p.L1087V | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.967); catalogued as COSV56249954; called by muse, mutect2
- MAST4 | c.4270G>A p.V1424I (on ENST00000403625 / NM_001164664.2; = p.V1235I on NM_015183.3) | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as COSV55146007; called by muse, mutect2, varscan2
- MC5R | c.674C>T p.A225V | Missense Mutation (SNP) | VAF 19/268 reads (7%) | SIFT tolerated (0.6); PolyPhen benign (0.079); catalogued as COSV61255964; called by muse, mutect2
- MID1 | c.973C>T p.H325Y | Missense Mutation (SNP) | VAF 10/188 reads (5%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV58201004; called by muse, mutect2
- NLRX1 | c.2392G>A p.V798M | Missense Mutation (SNP) | VAF 22/213 reads (10%) | SIFT tolerated (0.21); PolyPhen benign (0.051); catalogued as rs751553782, COSV52705168; called by muse, mutect2, varscan2
- NMD3 | c.249G>C p.L83F | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.639); catalogued as COSV63619887; called by muse, mutect2, varscan2
- OR10R2 | c.137C>A p.A46D | Missense Mutation (SNP) | VAF 11/179 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.105); catalogued as COSV63769698; called by muse, mutect2
- OR2AK2 | c.423C>A p.C141* | Nonsense Mutation (SNP) | VAF 41/226 reads (18%) | catalogued as COSV63551134; called by muse, mutect2, varscan2
- OR5T3 | c.823A>T p.S275C | Missense Mutation (SNP) | VAF 9/134 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV57380938, COSV57382707, COSV57383013; called by muse, mutect2
- PAPPA | c.3968A>G p.N1323S | Missense Mutation (SNP) | VAF 7/83 reads (8%) | SIFT tolerated (0.75); PolyPhen benign (0.033); catalogued as COSV60293931; called by muse, mutect2
- PAPPA | c.4087C>T p.R1363* | Nonsense Mutation (SNP) | VAF 5/77 reads (6%) | catalogued as COSV60293937; called by muse, mutect2
- PIK3C3 | c.1976G>A p.R659Q | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.072); catalogued as rs1331467644, COSV56285890; called by muse, mutect2
- PLSCR5 | c.398C>G p.T133R | Missense Mutation (SNP) | VAF 7/122 reads (6%) | SIFT tolerated (0.54); PolyPhen benign (0.104); catalogued as COSV71649312; called by muse, mutect2
- POU3F1 | c.875C>A p.T292N | Missense Mutation (SNP) | VAF 12/132 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65949521; called by muse, mutect2
- PREPL | c.868G>A p.V290I | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT tolerated (0.33); PolyPhen benign (0.033); catalogued as COSV53215445, COSV53219907; called by muse, mutect2
- PSIP1 | c.1256T>G p.L419W | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66255960; called by muse, mutect2, varscan2
- SORCS1 | c.2596C>T p.R866C | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs776376944, COSV53858615; called by muse, mutect2
- SPATA31D1 | c.13C>G p.L5V | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.328); catalogued as rs778186579, COSV61202373; called by muse, mutect2, varscan2
- SPTA1 | c.958-2A>C p.X320_splice | Splice Site (SNP) | VAF 18/198 reads (9%) | catalogued as COSV63761344; called by muse, mutect2
- TAF1L | c.3391A>G p.K1131E | Missense Mutation (SNP) | VAF 10/126 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.752); catalogued as COSV54265275; called by muse, mutect2
- TSPYL6 | c.1091G>C p.R364T | Missense Mutation (SNP) | VAF 7/82 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.484); catalogued as COSV104399815, COSV57821375; called by muse, mutect2
- VASH1 | c.862G>A p.D288N | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as rs983058154, COSV51336958; called by muse, mutect2
- WDR49 | c.796T>C p.F266L (on ENST00000308378 / NM_001366158.1; = p.F607L on NM_001348951.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV57719644; called by muse, mutect2, varscan2
- ZNF256 | c.1700G>C p.R567T | Missense Mutation (SNP) | VAF 7/87 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.85); catalogued as COSV56600270; called by muse, mutect2
- ZNF518B | c.2461T>G p.S821A | Missense Mutation (SNP) | VAF 8/136 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.039); catalogued as COSV58725233; called by muse, mutect2
- ZNF540 | c.1463T>G p.I488S | Missense Mutation (SNP) | VAF 11/108 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.042); catalogued as COSV57111940; called by muse, mutect2, varscan2
- IFNA10 | c.267T>A p.N89K | Missense Mutation (SNP) | VAF 8/154 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.211); called by muse, mutect2
- KIR3DL2 | c.508C>A p.Q170K | Missense Mutation (SNP) | VAF 44/508 reads (9%) | SIFT tolerated (0.35); PolyPhen benign (0.101); called by muse, mutect2
- ADGRF1 | c.972A>G p.S324= | Silent (SNP) | VAF 8/130 reads (6%) | catalogued as COSV51948359; called by muse, mutect2
- COMP | c.1104C>T p.G368= | Silent (SNP) | VAF 12/202 reads (6%) | catalogued as CD982557, COSV55876808; called by muse, mutect2
- CWH43 | c.1032C>T p.Y344= | Silent (SNP) | VAF 5/37 reads (14%) | catalogued as rs151323921; called by muse, mutect2
- FKBP4 | c.1230C>T p.L410= | Silent (SNP) | VAF 112/244 reads (46%) | catalogued as rs762943432, COSV50010283; called by muse, mutect2, varscan2
- GALNT16 | c.237G>A p.L79= | Silent (SNP) | VAF 6/118 reads (5%) | catalogued as COSV61888594; called by muse, mutect2
- IL12RB1 | c.876G>A p.P292= | Silent (SNP) | VAF 16/55 reads (29%) | catalogued as rs757032676, COSV59099975; called by muse, mutect2, varscan2
- KRTAP13-3 | c.273T>C p.S91= | Silent (SNP) | VAF 8/67 reads (12%) | catalogued as COSV61879462, COSV61879897, COSV61880010; called by muse, mutect2, varscan2
- MFSD6L | c.1146C>T p.V382= | Silent (SNP) | VAF 10/82 reads (12%) | catalogued as COSV100266048; called by mutect2, varscan2
- MUC16 | c.31056T>A p.T10352= | Silent (SNP) | VAF 7/109 reads (6%) | catalogued as COSV67501757; called by muse, mutect2
- MYO1H | c.1134C>T p.I378= | Silent (SNP) | VAF 10/70 reads (14%) | catalogued as COSV60452169; called by muse, mutect2, varscan2
- NAP1L3 | c.274T>C p.L92= | Silent (SNP) | VAF 10/51 reads (20%) | catalogued as rs1476397464, COSV59078117; called by muse, mutect2
- OR2M5 | c.513T>C p.S171= | Silent (SNP) | VAF 18/412 reads (4%) | catalogued as COSV63547233; called by muse, mutect2
- RAB11FIP5 | c.687C>G p.G229= | Silent (SNP) | VAF 9/150 reads (6%) | catalogued as COSV50261340; called by muse, mutect2
- SLC45A2 | c.1089C>T p.Y363= | Silent (SNP) | VAF 14/174 reads (8%) | catalogued as rs148156477; ClinVar: uncertain significance; called by muse, mutect2
- STK24 | c.867T>C p.N289= | Silent (SNP) | VAF 7/75 reads (9%) | catalogued as rs1222216482, COSV64823962; called by muse, mutect2
- TMPRSS7 | c.2490C>T p.N830= (on ENST00000452346; = p.N704= on NM_001042575.2) | Silent (SNP) | VAF 8/117 reads (7%) | catalogued as COSV69982912; called by muse, mutect2
- TRDV2 | c.216G>A p.K72= | Silent (SNP) | VAF 15/115 reads (13%) | called by muse, mutect2, varscan2
- UBE3C | c.2718G>A p.G906= | Silent (SNP) | VAF 8/46 reads (17%) | catalogued as rs781644342, COSV61956028; called by muse, mutect2, varscan2
- ZNF521 | c.2532A>C p.T844= | Silent (SNP) | VAF 11/198 reads (6%) | catalogued as COSV64133034; called by muse, mutect2
- ZNF543 | c.657G>C p.R219= | Silent (SNP) | VAF 6/90 reads (7%) | catalogued as COSV100386769, COSV58629794; called by muse, mutect2
- AL353804.7 | chrX:73851490 C>T | 3'Flank (SNP) | VAF 10/218 reads (5%) | called by muse, mutect2
- SNORD116-29 | n.27A>C | RNA (SNP) | VAF 8/82 reads (10%) | called by muse, mutect2
- TTN | c.10361-4023A>G | Intron (SNP) | VAF 8/106 reads (8%) | catalogued as COSV60411278; called by muse, mutect2
